Somatic mutation profile of tumor specimen TCGA-CF-A47S-01A (aliquot TCGA-CF-A47S-01A-11D-A23U-08) from TCGA case TCGA-CF-A47S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 41.7 years (15,225 days).
Specimen TCGA-CF-A47S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed14e312-3c86-4e6d-a2f9-56f75207294a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A47S-10A (Blood Derived Normal), aliquot TCGA-CF-A47S-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/519a5e5d-4ea8-46dc-a315-9bb7cca2548c

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53578390; called by muse, mutect2, varscan2
- AIMP2 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV52241201; called by muse, mutect2, varscan2
- AIMP2 | c.873C>G p.C291W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV52241209; called by muse, mutect2, varscan2
- CBR1 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99289392; called by muse, mutect2, varscan2
- CBR1 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51739572; called by muse, mutect2, varscan2
- COL9A1 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100610931; called by muse, mutect2, varscan2
- GABBR1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs768981978, COSV63543527; called by muse, mutect2, varscan2
- MYH11 | c.5051del p.S1684Tfs*72 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | catalogued as COSV55561115; called by mutect2, pindel, varscan2
- NYNRIN | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs775781760, COSV66843656; called by muse, mutect2, varscan2
- PCDHA3 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100793723, COSV63542265; called by muse, mutect2, varscan2
- PGR | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs149186732; called by muse, mutect2, varscan2
- RND1 | c.40T>A p.C14S | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV59045734; called by muse, mutect2, varscan2
- SLC11A1 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1297288244, COSV99261860; called by muse, mutect2, varscan2
- SPTAN1 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV63985297; called by muse, mutect2
- STOML2 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223657497, COSV53052362, COSV53053974; called by muse, mutect2, varscan2
- TRMT61B | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60258470; called by mutect2, varscan2
- WDR81 | c.4820C>T p.P1607L (on ENST00000409644 / NM_001163809.2; = p.P556L on NM_152348.4) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs780051043, COSV58485264; called by muse, mutect2, varscan2
- WNT5B | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60197644; called by muse, mutect2, varscan2
- ZNF564 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59435779; called by muse, mutect2, varscan2
- ACTB | c.328dup p.L110Pfs*16 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- AHNAK | c.6289G>A p.E2097K | Missense Mutation (SNP) | VAF 6/188 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.167); called by muse, mutect2
- CTBP2 | c.898_901del p.E301Pfs*9 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.358_361del p.L120Sfs*3 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.285dup p.E96Rfs*29 | Frame Shift Ins (INS) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- DKK1 | c.216T>C p.N72= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV64760547; called by muse, mutect2, varscan2
- MMP19 | c.741T>C p.D247= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV59452164; called by muse, mutect2, varscan2
- NDST1 | c.2097C>T p.V699= | Silent (SNP) | VAF 11/217 reads (5%) | catalogued as COSV55788870; called by muse, mutect2
- TOR1A | c.489G>A p.A163= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs576068168, COSV100693905, COSV61029135; called by muse, mutect2, varscan2
- TRAFD1 | c.138T>C p.F46= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV57505232; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7254G>A | Intron (SNP) | VAF 14/51 reads (27%) | catalogued as COSV57710324; called by muse, mutect2, varscan2
